Somatic mutation profile of tumor specimen TCGA-AC-A62X-01A (aliquot TCGA-AC-A62X-01A-11D-A29N-09) from TCGA case TCGA-AC-A62X, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 72.9 years (26,627 days).
Specimen TCGA-AC-A62X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e1caf54-66c6-4bcd-8012-7021057d33f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AC-A62X-10A (Blood Derived Normal), aliquot TCGA-AC-A62X-10A-01D-A29N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27c4c890-433f-453f-ba34-777015aac0c5

The open-access MAF lists 54 somatic variants for this specimen: 42 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 11, Frame Shift Del 1, Frame Shift Ins 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 30/42 reads (71%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACOXL | c.548G>A p.G183D | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201679805, COSV61329590; called by muse, mutect2, varscan2
- AFDN | c.4849G>C p.E1617Q (on ENST00000447894 / NM_001366320.1; = p.E1615Q on NM_001040000.3) | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV60054021; called by muse, mutect2, varscan2
- AMMECR1L | c.838G>A p.V280M | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.062); catalogued as rs765978994, COSV55761687; called by muse, mutect2, varscan2
- ARHGEF26 | c.1955C>T p.S652F | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62850872; called by muse, mutect2, varscan2
- CACNA1E | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1373949411, COSV62413970; called by muse, mutect2, varscan2
- CDH23 | c.1699G>A p.V567M | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as rs377148854; called by muse, mutect2, varscan2
- CGB1 | c.380C>A p.T127N | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.184); catalogued as COSV56820982; called by muse, mutect2, varscan2
- CLCN7 | c.272C>G p.S91C | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV51973165; called by muse, mutect2, varscan2
- CPSF1 | c.566A>G p.Y189C | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62942052; called by muse, mutect2, varscan2
- DMD | c.9229G>A p.E3077K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as COSV58943990; called by muse, mutect2, varscan2
- FBXL19 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.801); catalogued as rs1160473639, COSV57945184; called by muse, mutect2, varscan2
- FOXL2 | c.207G>T p.E69D | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.079); catalogued as COSV57726404, COSV57729898; called by muse, mutect2
- GGN | c.1270G>T p.G424C | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.835); catalogued as COSV53058562; called by muse, mutect2, varscan2
- GIGYF1 | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.027); catalogued as rs760618499, COSV51946048, COSV51947637; called by muse, mutect2, varscan2
- H3C2 | c.237C>A p.F79L | Missense Mutation (SNP) | VAF 45/174 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.349); catalogued as rs753530015, COSV52518427, COSV52519695; called by muse, mutect2, varscan2
- HHIPL1 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.559); catalogued as rs753488026, COSV58090787; called by muse, mutect2, varscan2
- IL17RD | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 47/59 reads (80%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.58); catalogued as rs139866451; called by muse, mutect2, varscan2
- ITGA1 | c.2846G>C p.G949A | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.595); catalogued as COSV50894517; called by muse, mutect2, varscan2
- KIAA1328 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs536436186, COSV54448669; called by muse, mutect2, varscan2
- LILRA5 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.053); catalogued as rs568171861, COSV56644835; called by muse, mutect2, varscan2
- LTK | c.1876G>A p.D626N | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53029040; called by muse, mutect2, varscan2
- LUZP2 | c.256G>T p.E86* | Nonsense Mutation (SNP) | VAF 16/52 reads (31%) | catalogued as COSV61216008; called by muse, mutect2, varscan2
- MAVS | c.1460C>T p.A487V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.087); catalogued as rs762014329, COSV63927462; called by muse, mutect2, varscan2
- MCF2L2 | c.2032G>A p.E678K | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs1439517800, COSV61049919; called by muse, mutect2
- MICAL2 | c.1865G>T p.R622L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs199894889, COSV56316453; called by muse, mutect2, varscan2
- MSX2 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.471); catalogued as rs1165916964, COSV53328136; called by muse, mutect2, varscan2
- NLRX1 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.745); catalogued as rs544880461, COSV52708580; called by muse, mutect2, varscan2
- NUP210L | c.2961G>C p.E987D | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.96); PolyPhen probably damaging (0.978); catalogued as COSV55158022, COSV99667558; called by muse, mutect2
- OAS2 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.264); catalogued as rs568482198, COSV60804148; called by muse, mutect2, varscan2
- OGFRL1 | c.845A>G p.Y282C | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64972397; called by muse, mutect2, varscan2
- PALLD | c.1354G>A p.V452M | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs187404166, COSV54991983; called by muse, mutect2, varscan2
- PLEKHA6 | c.2461G>T p.V821L | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as COSV55339257; called by muse, mutect2, varscan2
- PLEKHF1 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs780377669, COSV71410115; called by muse, mutect2, varscan2
- SALL1 | c.3080G>A p.R1027K | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.924); catalogued as COSV51754991, COSV51763255; called by muse, mutect2, varscan2
- SEZ6 | c.948C>A p.F316L | Missense Mutation (SNP) | VAF 60/75 reads (80%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV57982027, COSV57984119; called by muse, mutect2, varscan2
- TEAD3 | c.1297G>A p.V433I | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs773682085, COSV58818298; called by muse, mutect2, varscan2
- TFIP11 | c.727G>A p.V243M | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as rs147540948; called by muse, mutect2, varscan2
- TNXB | c.9826G>A p.V3276M (on ENST00000647633; = p.V3029M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.805); catalogued as rs543265032, COSV64487261; called by muse, mutect2, varscan2
- TXNDC11 | c.1999T>G p.F667V (on ENST00000356957 / NM_001303447.2; = p.F640V on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV51602351; called by muse, mutect2, varscan2
- BAP1 | c.639dup p.I214Yfs*29 | Frame Shift Ins (INS) | VAF 31/47 reads (66%) | called by mutect2, pindel, varscan2
- PDE4B | c.1420_1430del p.V474Sfs*16 | Frame Shift Del (DEL) | VAF 11/78 reads (14%) | called by mutect2, pindel, varscan2
- ADARB2 | c.1707C>T p.G569= | Silent (SNP) | VAF 30/99 reads (30%) | catalogued as rs560087481, COSV67182028; called by muse, mutect2, varscan2
- DIP2A | c.4156C>T p.L1386= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV59485245; called by muse, mutect2, varscan2
- HTR2C | c.630C>T p.N210= | Silent (SNP) | VAF 77/201 reads (38%) | catalogued as rs782644122, COSV52222042; called by muse, mutect2, varscan2
- MAEL | c.189C>T p.A63= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV63304564, COSV63305966; called by muse, mutect2, varscan2
- OR2Y1 | c.714G>A p.G238= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV57136003; called by muse, mutect2, varscan2
- OR52A5 | c.684C>A p.V228= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV56615009, COSV56616479; called by muse, mutect2, varscan2
- PSIP1 | c.921T>C p.H307= | Silent (SNP) | VAF 18/170 reads (11%) | catalogued as COSV101050912; called by muse, mutect2, varscan2
- SEL1L3 | c.3384G>A p.P1128= | Silent (SNP) | VAF 39/71 reads (55%) | catalogued as rs535461601, COSV53548120; called by muse, mutect2, varscan2
- TENM3 | c.7476C>A p.V2492= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV69316770; called by muse, mutect2, varscan2
- TGM6 | c.1989G>A p.Q663= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs758596546, COSV52483418; called by muse, mutect2, varscan2
- TMEM100 | c.216C>T p.T72= | Silent (SNP) | VAF 45/51 reads (88%) | catalogued as rs755197957, COSV70118278; called by muse, mutect2, varscan2
- FBLN1 | c.1698-11496G>A | Intron (SNP) | VAF 22/65 reads (34%) | catalogued as rs1270604579, COSV53052968; called by muse, mutect2, varscan2
